Somatic mutation profile of tumor specimen TCGA-28-1753-01A (aliquot TCGA-28-1753-01A-01D-1494-08) from TCGA case TCGA-28-1753, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.0 years (19,366 days).
Specimen TCGA-28-1753-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6ddd668-98e6-43a4-a738-29ae46cce681.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-1753-10B (Blood Derived Normal), aliquot TCGA-28-1753-10B-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/615a2810-bb54-4bac-834e-4a07ed36e1bc

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Nonsense Mutation 2, RNA 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1008C>A p.Y336* | Nonsense Mutation (SNP) | VAF 47/129 reads (36%) | hotspot (GDC flag); catalogued as COSV64292408, COSV64294380, COSV64309461; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.8765C>T p.P2922L | Missense Mutation (SNP) | VAF 144/526 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as COSV52174826; called by muse, mutect2, varscan2
- ARHGEF5 | c.603T>A p.S201R | Missense Mutation (SNP) | VAF 34/658 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs1398156451, COSV50210023, COSV50213730; called by muse, mutect2
- BARD1 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs1553622620, COSV53610401, COSV53614425; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBY2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs1399175372, COSV60117172; called by muse, mutect2, varscan2
- CYP4X1 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.475); catalogued as rs965440714, COSV64150805; called by muse, mutect2, varscan2
- DOCK5 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs994166763, COSV52406662; called by muse, mutect2, varscan2
- E2F7 | c.1334T>C p.I445T | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs1195925377, COSV59741839; called by muse, mutect2, varscan2
- FCRLA | c.850C>T p.Q284* (on ENST00000367959; = p.Q261* on NM_032738.4) | Nonsense Mutation (SNP) | VAF 27/109 reads (25%) | catalogued as COSV52687010; called by muse, mutect2, varscan2
- FGD5 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs749435304, COSV53247320; called by muse, mutect2
- GDPD2 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 86/149 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs745627490, COSV65532049; called by muse, mutect2, varscan2
- IPPK | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs146634367; called by muse, mutect2, varscan2
- IRS4 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV64532810, COSV64532831; called by muse, mutect2
- ITGA4 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs758516673, COSV52002097; called by muse, mutect2, varscan2
- ITSN1 | c.4379C>T p.P1460L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768735426, COSV67157351; called by muse, mutect2, varscan2
- KIF2B | c.1066T>A p.F356I | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV52133123; called by muse, mutect2, varscan2
- KIF5B | c.2747A>G p.H916R | Missense Mutation (SNP) | VAF 167/349 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs200775134; called by muse, mutect2, varscan2
- LRP2 | c.9124G>A p.G3042R | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs376039022; called by muse, mutect2, varscan2
- MARCO | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.198); catalogued as rs200590124; called by muse, mutect2, varscan2
- MSLNL | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as rs548772489, COSV53504123; called by muse, mutect2, varscan2
- NEB | c.9346G>A p.E3116K | Missense Mutation (SNP) | VAF 153/483 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as rs374359052; called by muse, mutect2, varscan2
- NPAP1 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1397820294, COSV61508092; called by muse, mutect2, varscan2
- NXF3 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 147/237 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs764974230, COSV67703146; called by muse, mutect2, varscan2
- POLR1G | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as rs751999730, COSV99185282; called by mutect2, varscan2
- RPH3A | c.905C>T p.P302L (on ENST00000389385 / NM_001143854.2; = p.P298L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1340387856, COSV66991234; called by muse, mutect2, varscan2
- RSKR | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.567); catalogued as COSV56382960; called by muse, mutect2
- RYR2 | c.3898A>G p.M1300V | Missense Mutation (SNP) | VAF 114/405 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV63698866; called by muse, mutect2, varscan2
- SIPA1L3 | c.3839G>T p.S1280I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55919303; called by muse, mutect2, varscan2
- SLBP | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV59184087; called by muse, mutect2, varscan2
- SLC7A1 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV66331105; called by muse, mutect2, varscan2
- TEKT4 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.146); catalogued as rs781986882, COSV54626609; called by muse, mutect2, varscan2
- TTN | c.68290G>A p.E22764K (on ENST00000591111; = p.E15340K on NM_003319.4) | Missense Mutation (SNP) | VAF 30/87 reads (34%) | PolyPhen possibly damaging (0.615); catalogued as rs764485436, COSV59907992; called by muse, mutect2, varscan2
- UHRF2 | c.11A>G p.Q4R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as COSV52794492; called by muse, mutect2, varscan2
- USH1G | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368407264; called by muse, mutect2, varscan2
- WEE2 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs770227288, COSV66878549; called by muse, mutect2
- ZFP42 | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 85/351 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV58818377; called by muse, mutect2, varscan2
- CDKN2C | c.150del p.E51Rfs*15 | Frame Shift Del (DEL) | VAF 66/242 reads (27%) | called by mutect2, pindel, varscan2
- CD36 | c.843C>T p.S281= | Silent (SNP) | VAF 105/515 reads (20%) | catalogued as rs372529585; called by muse, mutect2, varscan2
- CYP4A22 | c.204C>T p.H68= | Silent (SNP) | VAF 31/159 reads (19%) | catalogued as rs370585374; called by muse, mutect2, varscan2
- DIP2A | c.1659C>T p.N553= | Silent (SNP) | VAF 67/522 reads (13%) | catalogued as rs372959959; called by muse, mutect2, varscan2
- DOCK5 | c.3249C>T p.I1083= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs780661201, COSV52402395; called by muse, mutect2, varscan2
- HCRTR1 | c.420C>T p.I140= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as rs140406432; called by muse, mutect2, varscan2
- LARP6 | c.300C>T p.I100= | Silent (SNP) | VAF 96/244 reads (39%) | catalogued as rs760707940, COSV54579530; called by muse, mutect2, varscan2
- RFX6 | c.696G>A p.S232= | Silent (SNP) | VAF 73/213 reads (34%) | catalogued as rs1279349626, COSV60587165; called by muse, mutect2, varscan2
- SPEG | c.4578C>T p.T1526= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs202153500, COSV56674908; called by muse, mutect2, varscan2
- SPPL2A | c.730T>C p.L244= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV55942192; called by muse, mutect2, varscan2
- SUSD2 | c.1455G>A p.A485= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs539884627, COSV64204115; called by muse, mutect2, varscan2
- TES | c.915C>T p.D305= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs201867376, COSV64043022; called by muse, mutect2, varscan2
- TPTE | c.375G>A p.E125= (on ENST00000618007 / NM_199261.4; = p.E107= on NM_199259.4) | Silent (SNP) | VAF 11/205 reads (5%) | called by muse, mutect2
- OR3A4P | n.1250G>A | RNA (SNP) | VAF 42/153 reads (27%) | catalogued as rs766433554; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18535C>T | Intron (SNP) | VAF 11/26 reads (42%) | catalogued as COSV67446991; called by muse, mutect2, varscan2
- SSX6P | n.285C>T | RNA (SNP) | VAF 11/17 reads (65%) | catalogued as rs782427659; called by muse, mutect2, varscan2
